Somatic mutation profile of tumor specimen TARGET-10-PASKIC-09A (aliquot TARGET-10-PASKIC-09A-01D) from TARGET case TARGET-10-PASKIC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,092 days).
Specimen TARGET-10-PASKIC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 551e6828-5e9d-4050-abf1-a4c69146107a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASKIC-10A (Blood Derived Normal), aliquot TARGET-10-PASKIC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b39c78ef-e1f2-4a20-9621-881fb9b09da9

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 3, Frame Shift Ins 1, RNA 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APOH | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as rs150681833, COSV52771433; called by muse, varscan2
- CORO7-PAM16 | c.2806G>A p.V936M | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as rs779163926, COSV52109375; called by muse, mutect2, varscan2
- DNAH11 | c.6478C>A p.L2160I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60938172; called by muse, mutect2
- GRIK2 | c.2497C>A p.L833I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.624); catalogued as COSV59712821; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- NRAS | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as COSV54736754; called by muse, mutect2
- STAT6 | c.543G>T p.M181I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1478463241; called by muse, mutect2, varscan2
- ZIM3 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV54140002; called by muse, mutect2, varscan2
- IRAG1 | c.2017G>T p.E673* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- LAMA1 | c.2884G>T p.G962C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- LEF1 | c.391_392insCCAC p.L131Pfs*12 | Frame Shift Ins (INS) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.1602G>A p.Q534= | Silent (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- LUZP1 | c.2559G>T p.L853= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- NLRP10 | c.1404C>T p.S468= | Silent (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- PCDHA5 | c.1350C>T p.N450= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs61730629, COSV65348992; called by muse, mutect2
- SLC39A11 | c.75G>T p.G25= | Silent (SNP) | VAF 50/123 reads (41%) | catalogued as COSV99722494; called by muse, mutect2, varscan2
- AP000769.1 | n.104C>A | RNA (SNP) | VAF 4/46 reads (9%) | catalogued as rs1318596249; called by muse, mutect2
- NRIP2 | c.*54G>T | 3'UTR (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- RAVER1 | c.1173+64G>T | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
